FM case AD2270 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/3e79a985-690c-48cf-805e-b252f730a6a3

Female, 64.0 years: Carcinoma, NOS (ICD-O-3 8010/3) of the major salivary gland; primary biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
